Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6366, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6366-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. PROSTATE

TCGA - G9 - 6366

SPECIMEN(S):

A. PROSTATE

GROSS DESCRIPTION:

A. PROSTATE

Received fresh labeled with the patient's identification and designated "prostate" is an intact resected prostate gland weighing 92 g and measuring 7-cm from right to left, 5-cm from anterior to posterior, and 4-cm from apex to base. The capsule is smooth and red. Ink code: Apex - red, anterior-orange, posterior-black, base- blue, right-green, left-yellow. The apex and base are removed from the specimen to yield a new weight of 57 g. The specimen is serially sectioned from apex to base revealing tan fibrous bulging parenchyma and focal brown calcified concretions. The right and left seminal vesicle, 3 x 1.5 x 0.5 cm and 3.2 x 1.7 x 0.4 cm, respectively, are bisected to show beige tan cystic tissue. The right and left vas deferens, 3 x 0.5 cm and 1.5 x 0.5 cm, respectively, are sectioned to show firm tan tube structure. A portion of the specimen is submitted for tissue procurement, the remainder entirely submitted:

A1-A4: Right apex
A5-A8: Left Apex
A9: Level 1 right anterior
A10: Level 1 right mid
A11: Level 1 right posterior
A12: Level 1 left anterior
A13: Level 1 left mid
A14: Level 1 left posterior
A15: Level 2 capsule right side
A16-A17: Level 2 capsule left side
A18: Level 3 capsule right side
A19-A20: Level 3 capsule left side
A21-A23: Right lateral base
A24-A27: Right base
A28: Right base and proximal urethral margin
A29: Left base and proximal urethral margin
A30: Left base
A31-A33: Left lateral base
A34: Right seminal vesicle, right vas deferens
A35: Left seminal vesicle, left vas deferens

DIAGNOSIS:

A. PROSTATE, RADICAL PROSTATECTOMY:

- PROSTATIC ADENOCARCINOMA, GLEASON SCORE 4+3=7 (7/10)
INVOLVING APPROXIMATELY 4% OF EXAMINED GLAND AND EXTENDING INTO THE LEFT SEMINAL VESICLE WALL
- LEFT POSTERIOR MARGIN FOCALLY INVOLVED
- FOCAL EXTRAPROSTATIC EXTENSION IDENTIFIED.

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: PROSTATE

Location: Left

Posterior lateral

Apical

Basal

Anterior

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 4%

[page 2 of 2]
Gleason Grade/Sum:: Grade 4 + 3 , Sum 7
High Grade PIN Present: Yes
Perineural Invasion: Yes
Vascular/Lymphatic Invasion: No
Seminal Vesicle Invasion: Yes
Left
Muscular Wall Invasion: Yes
Lumen Invasion: No
Periprostatic Fat Involved: Yes
Details: left posterior
Bladder Neck Involved: No
Margins Involvement: No
Frozen Performed: No
Post Hormonal Therapy Change: No
Lymph Nodes: No lymph nodes sampled
Other Pathologic Findings: None identified
Pathological Staging (pTNM): T 3b N x M x
Comment(s): The single focus of positive margin is in block A17 and measures 0.6 mm

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Prostate carcinoma

Source: NCI Genomic Data Commons file 772b584b-6e10-4582-82c0-5edb40e149c0 (TCGA-G9-6366.6EF07861-A4DB-4AA2-BA73-4CD43E10D72F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).